Somatic mutation profile of tumor specimen TCGA-06-0141-01A (aliquot TCGA-06-0141-01A-01D-1490-08) from TCGA case TCGA-06-0141, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 62.8 years (22,926 days).
Specimen TCGA-06-0141-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b399ab78-cc6b-425d-9827-ea405d72c61b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0141-10A (Blood Derived Normal), aliquot TCGA-06-0141-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/300bbdde-ec44-4e36-90f3-af22a109e3f5

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC2 | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57160794, COSV57163502; called by muse, mutect2, varscan2
- CATSPER4 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267577595, COSV58792515; called by muse, mutect2
- DCAF12L2 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776609885, COSV100758723, COSV63580588; called by muse, mutect2, varscan2
- GFPT1 | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61946945; called by muse, mutect2
- KLRC3 | c.112A>G p.I38V | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761626461, COSV67250105; called by muse, mutect2
- LRRC66 | c.68A>G p.N23S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV58632463; called by muse, mutect2, varscan2
- N4BP2 | c.2839G>T p.G947* | Nonsense Mutation (SNP) | VAF 9/115 reads (8%) | catalogued as COSV54699996; called by muse, mutect2
- SACS | c.1756T>C p.Y586H | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV66536143; called by muse, mutect2
- TMCC3 | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV54152778; called by muse, mutect2
- UBE3A | c.392A>G p.E131G | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV51662157; called by muse, mutect2
- ZFAT | c.3125A>C p.K1042T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64735750; called by muse, mutect2, varscan2
- ZNF28 | c.1951G>A p.V651I | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.249); catalogued as rs146037495, COSV60422125, COSV60426241; called by muse, mutect2
- ANK3 | c.8730C>T p.N2910= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs370563122; called by muse, mutect2
- PCDHA13 | c.1824G>A p.S608= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs1443036011, COSV56474765; called by muse, mutect2
- PCDHB14 | c.1506C>A p.S502= | Silent (SNP) | VAF 21/242 reads (9%) | catalogued as COSV53387032; called by muse, mutect2
